Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6823, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6823-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: M

Material: **Lesion resection - tongue**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Tumour of the tongue and mouth floor on the right side. Biopsy result: Carcinoma planoepitheliale keratodes (G2).**

Examination performed on:

Macroscopic description:

Surgical specimen sized 5 x 4 x 2.5 with containing a fragment of the tongue and mucous membrane of the mouth floor. Material unmarked. A cream-coloured, crisp tumour occupying nearly whole of the specimen (tumour sized 3.5 x 1.8 x 2.5 cm).

Microscopic description:

Carcinoma planoepitheliale partim keratodes G2. The largest dimension of the lesion: 3.5 cm. Minimal margin of normal tissues from the edge of the specimen - unknown.

Histopathological Diagnosis:

Carcinoma planoepitheliale partim keratodes. Squamous and partially keratinized carcinoma of the skin, G2, pT2.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 09164262-0d0b-4f71-a2a4-1e0ff845e998 (TCGA-D6-6823.C4CC6A5A-5DE3-4AE0-AFBE-22EE499D2322.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).